Somatic mutation profile of tumor specimen MP2PRT-PASRFJ-TMP1-A (aliquot MP2PRT-PASRFJ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASRFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,264 days).
Specimen MP2PRT-PASRFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d3bd898-0244-44d0-a4dd-aa2577be63bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRFJ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56457a91-972a-497f-ad5c-c50a0787a194

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 40/137 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- AFAP1 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.874); catalogued as rs1392958475; called by muse, mutect2
- CSMD3 | c.1582C>T p.R528W (on ENST00000297405 / NM_001363185.1; = p.R424W on NM_052900.3) | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138791171; called by muse, mutect2
- IL1RAPL2 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 149/442 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs765978518, COSV61142261; called by muse, mutect2, varscan2
- PLA2G4E | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 120/333 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs915872572; called by muse, mutect2, varscan2
- PTPRM | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs756195807; called by muse, mutect2, varscan2
- SLC9A2 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs774494897, COSV52132917; called by muse, mutect2
- TLL2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV63575343; called by muse, mutect2, varscan2
- CDH9 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NXF1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 85/287 reads (30%) | called by muse, mutect2, varscan2
- C5orf49 | c.183G>A p.K61= | Silent (SNP) | VAF 64/207 reads (31%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1419G>A p.P473= | Silent (SNP) | VAF 107/303 reads (35%) | catalogued as rs372724261; called by muse, mutect2, varscan2
- GREB1L | c.3582G>A p.A1194= | Silent (SNP) | VAF 340/588 reads (58%) | catalogued as rs1394202414; called by muse, varscan2
- MARF1 | c.4926C>T p.P1642= | Silent (SNP) | VAF 133/431 reads (31%) | catalogued as rs751612004; called by muse, mutect2, varscan2
- MSI1 | c.951C>T p.A317= | Silent (SNP) | VAF 162/534 reads (30%) | called by muse, mutect2, varscan2
- NGFR | c.378C>T p.R126= | Silent (SNP) | VAF 67/979 reads (7%) | catalogued as rs531801447; called by muse, mutect2
